TCGA case TCGA-N9-A4Q3 — Uterine Carcinosarcoma (TCGA-UCS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Uterus, NOS; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/83059a0f-4de9-454c-8e51-9265ab5f3558

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Alive.

Diagnoses (5)
1. Mullerian mixed tumor (the primary disease): ICD-O-3 morphology code: 8950/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 65.8 years (24,031 days); Year of diagnosis: 2009; Method of diagnosis: Biopsy; FIGO stage: Stage IA; FIGO staging edition year: 2009; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,672 days (4.6 years).
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 5.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 20.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 0.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 771 days (2.1 years); Days to treatment end: 1,128 days (3.1 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 1,219 days (3.3 years); Days to treatment end: 1,249 days (3.4 years); Treatment dose: 42 Gy; Treatment outcome: Stable Disease; Number of fractions: 14; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Days to treatment start: 1,470 days (4.0 years); Days to treatment end: 1,555 days (4.3 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 1,598 days (4.4 years); Days to treatment end: 1,633 days (4.5 years); Treatment dose: 42 Gy; Treatment outcome: Progressive Disease; Number of fractions: 14; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 1,598 days (4.4 years); Days to treatment end: 1,633 days (4.5 years); Treatment dose: 30 Gy; Treatment outcome: Progressive Disease; Number of fractions: 10; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Metastasis of diagnosis 1 (Mullerian mixed tumor), site: Lung, NOS. Age at diagnosis: 67.8 years (24,766 days); Days to diagnosis: 735 days (2.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 748 days (2.0 years); Residual disease: R2.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
3. Metastasis of diagnosis 1 (Mullerian mixed tumor), site: Lymph node, NOS. Age at diagnosis: 67.8 years (24,766 days); Days to diagnosis: 735 days (2.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
4. Metastasis of diagnosis 1 (Mullerian mixed tumor), site: Thorax, NOS. Age at diagnosis: 70.1 years (25,614 days); Days to diagnosis: 1,583 days (4.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
5. Metastasis of diagnosis 1 (Mullerian mixed tumor), site: Brain, NOS. Age at diagnosis: 70.2 years (25,626 days); Days to diagnosis: 1,595 days (4.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (6 entries)
- Day 735 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 735 days (2.0 years).
- Day 735 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 735 days (2.0 years).
- Day 1,583 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 1,583 days (4.3 years).
- Day 1,595 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 1,595 days (4.4 years).
- Days to follow up: 1,672 days (4.6 years); Disease response: With Tumor.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 90 kg; Height: 162 cm; BMI: 34.3.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: Yes; Menopause status: Postmenopausal; Number of pregnancies: 2; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-N9-A4Q3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 250 mg.
  Slide TCGA-N9-A4Q3-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 70; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 5.
- Sample TCGA-N9-A4Q3-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-N9-A4Q3-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History menopausal hormone therapy: Yes, I have taken menopausal hormone therapy in the past, but no longer do; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Pregnancies full term count: 2; History colorectal cancer: No; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response.
- Primary pathology: Submitted tumor site: Uterus; Anatomic organ subdivision: Endometrium; Histologic diagnosis: Uterine Carcinosarcoma/ Malignant Mixed Mullerian Tumor (MMMT): NOS; Surgical approach at diagnosis: Minimally Invasive; Method initial path diagnosis: Office Endometrial Biopsy.
- Drug treatment 3: Pharmaceutical therapy drug name: Doxil; Treatment best response: Clinical Progressive Disease.
- Radiation treatment 2: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,672 days; disease-specific survival: no event (censored), 1,672 days; disease-free interval: event (new tumor event after initially disease-free), 735 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 735 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-N9-A4Q3-01A-11D-A28Q-01): tumor purity 0.89, ploidy 3.29, whole-genome doublings 1.
